Somatic mutation profile of tumor specimen C3L-00917-01 (aliquot CPT0023690006) from CPTAC case C3L-00917, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 37.9 years (13,840 days).
Specimen C3L-00917-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97295e23-6321-4fa4-9617-b6f66a13bfbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00917-31 (Blood Derived Normal), aliquot CPT0024600002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dae84478-0a40-4010-adfa-9764a11bf7dc

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.341-2A>G p.X114_splice | Splice Site (SNP) | VAF 50/219 reads (23%) | hotspot (GDC flag); catalogued as rs869025637, CS071275, COSV56542830, COSV56544966, COSV56548666, COSV56554645; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF18 | c.1627G>A p.V543M (on ENST00000359920 / NM_001130955.2; = p.V439M on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1302262351; called by muse, mutect2, varscan2
- FYB2 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.172); catalogued as rs754394002; called by muse, mutect2, varscan2
- PDE6A | c.2426G>A p.W809* | Nonsense Mutation (SNP) | VAF 65/362 reads (18%) | catalogued as rs979416907; called by muse, mutect2, varscan2
- RC3H2 | c.2068A>G p.M690V | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1269338784; called by muse, mutect2, varscan2
- SOBP | c.2396dup p.D800Rfs*8 | Frame Shift Ins (INS) | VAF 59/315 reads (19%) | catalogued as rs751989931; called by mutect2, pindel, varscan2
- ADGRF5 | c.1208A>T p.E403V | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AKAP13 | c.3233C>G p.T1078S | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HDAC9 | c.1363C>A p.P455T | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXA1 | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IGLV4-69 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- MCHR1 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 88/369 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED13 | c.5551G>T p.V1851L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- OR52E6 | c.322T>A p.F108I | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RAD21 | c.943_946del p.E315Qfs*9 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel
- ZFHX3 | c.8430T>G p.I2810M | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRG4 | c.6150G>A p.A2050= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs770791343; called by muse, mutect2, varscan2
- CAPN2 | c.963T>C p.D321= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as rs547196428; called by muse, mutect2, varscan2
- MAGEB10 | c.624G>T p.L208= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as COSV63313039; called by muse, mutect2
- OR6A2 | c.444G>A p.Q148= | Silent (SNP) | VAF 61/277 reads (22%) | catalogued as COSV100215612, COSV60264323; called by muse, mutect2, varscan2
- PDE4D | c.93C>T p.R31= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs375580342; called by muse, mutect2, varscan2
- RRP12 | c.3492G>A p.K1164= | Silent (SNP) | VAF 46/267 reads (17%) | called by muse, mutect2, varscan2
- SERPINB3 | c.264T>C p.L88= | Silent (SNP) | VAF 45/226 reads (20%) | called by muse, mutect2, varscan2
- UMODL1 | c.1520-1201G>A | Intron (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- VSIG10L | c.*63G>A | 3'UTR (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
